Somatic mutation profile of tumor specimen 0DFSSJ from CCDI case PBBSSM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.4 years (2,333 days).
Specimen 0DFSSJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb8e72ca-0f5c-410c-8b35-03ae0856e25c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFSS4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4aeefcd-b398-457e-8808-f5a5a654ae3d

The open-access MAF lists 19 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 4, Silent 4, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 475/982 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 852/948 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MUC16 | c.1259C>T p.T420I | Missense Mutation (SNP) | VAF 373/460 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV67468229; called by muse, mutect2, varscan2
- MYPN | c.1567A>T p.T523S | Missense Mutation (SNP) | VAF 306/1178 reads (26%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.996); catalogued as COSV62733036; called by muse, mutect2, varscan2
- CCER1 | c.847A>G p.K283E | Missense Mutation (SNP) | VAF 692/2990 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- F5 | c.4318C>G p.P1440A | Missense Mutation (SNP) | VAF 459/1677 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- FRG2 | c.480G>C p.R160S | Missense Mutation (SNP) | VAF 173/397 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GHITM | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 235/904 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RMND5B | c.1118+1del p.X373_splice | Splice Site (DEL) | VAF 320/766 reads (42%) | called by mutect2, varscan2
- TTC12 | c.1660A>G p.I554V | Missense Mutation (SNP) | VAF 346/1015 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 18/372 reads (5%) | catalogued as rs1167537044; called by muse, mutect2
- FAT4 | c.4986A>G p.P1662= | Silent (SNP) | VAF 377/907 reads (42%) | catalogued as rs539231738; called by muse, mutect2, varscan2
- LPP | c.1446C>G p.P482= | Silent (SNP) | VAF 48/1104 reads (4%) | catalogued as COSV57079441; called by muse, mutect2
- PCDHGA10 | c.1617C>T p.S539= | Silent (SNP) | VAF 135/1206 reads (11%) | catalogued as COSV53933693; called by muse, mutect2, varscan2
- ANKRD40 | c.135-22A>G | Intron (SNP) | VAF 170/379 reads (45%) | catalogued as rs765023246; called by muse, varscan2
- CFAP65 | c.-2-93C>G | Intron (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- HERC1 | c.13689-37G>T | Intron (SNP) | VAF 11/173 reads (6%) | called by muse, mutect2
- TAF1L | c.-24C>T | 5'UTR (SNP) | VAF 119/786 reads (15%) | catalogued as rs773992512, COSV54268909; called by muse, mutect2, varscan2
- ZFYVE16 | c.3607+79C>T | Intron (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
